Somatic mutation profile of tumor specimen TCGA-BA-5559-01A (aliquot TCGA-BA-5559-01A-01D-1512-08) from TCGA case TCGA-BA-5559, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G3; Age at diagnosis: 72.0 years (26,286 days).
Specimen TCGA-BA-5559-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4b39ac4-c7c9-487e-b24e-c642e3feab06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-5559-10A (Blood Derived Normal), aliquot TCGA-BA-5559-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19226306-3479-4ea2-8c7a-37203d5aea1d

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 15, Nonsense Mutation 5, Splice Region 2, Frame Shift Del 2, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLD | c.1112C>A p.S371* | Nonsense Mutation (SNP) | VAF 7/139 reads (5%) | catalogued as rs886040872, CM001113, COSV61094720; ClinVar: pathogenic; called by muse, mutect2
- EP300 | c.3491G>A p.C1164Y | Missense Mutation (SNP) | VAF 116/195 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54335593, COSV54335605; called by muse, mutect2, varscan2
- ABCC10 | c.704G>A p.R235H (on ENST00000372530 / NM_001198934.2; = p.R192H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as rs200394501; called by muse, mutect2, varscan2
- ACSM2B | c.738T>G p.A246= | Splice Region (SNP) | VAF 28/151 reads (19%) | catalogued as COSV100312942, COSV61659223; called by muse, mutect2, varscan2
- ASAP1 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 42/608 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.815); catalogued as rs1212719499, COSV100727560; called by muse, mutect2
- ASZ1 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV52913632, COSV99498153; called by muse, mutect2
- ATP10B | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as rs780851806, COSV59147668; called by muse, mutect2, varscan2
- ATP7B | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV99666706; called by muse, mutect2, varscan2
- BRIP1 | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV99370579; called by muse, mutect2, varscan2
- CDC20 | c.395G>C p.R132P | Missense Mutation (SNP) | VAF 105/273 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.286); catalogued as COSV60521811, COSV60523785; called by muse, mutect2, varscan2
- CDH11 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV99219181; called by muse, mutect2
- CLEC1A | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100191586; called by muse, mutect2
- COL6A2 | c.1895C>A p.T632K | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as COSV100153905, COSV56002999; called by muse, mutect2
- DNAJC13 | c.2186G>T p.R729M | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99607678; called by muse, mutect2
- EFEMP2 | c.445T>A p.C149S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100337304; called by muse, mutect2, varscan2
- FXR1 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV99976522; called by muse, mutect2
- GREM2 | c.216G>C p.W72C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781668325, COSV100547290; called by muse, mutect2, varscan2
- IL2RB | c.1401G>T p.W467C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99345055; called by muse, mutect2
- IL9R | c.93C>A p.C31* | Nonsense Mutation (SNP) | VAF 56/211 reads (27%) | catalogued as rs1275990546, COSV99730020; called by muse, mutect2, varscan2
- INTS6 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100246885; called by muse, mutect2, varscan2
- ITCH | c.1190A>G p.Y397C (on ENST00000262650 / NM_001257137.3; = p.Y356C on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1248279016, COSV99392824; called by muse, mutect2, varscan2
- LAMA1 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745969754, COSV67541730; called by muse, mutect2, varscan2
- LRP1B | c.1788T>C p.D596= | Splice Region (SNP) | VAF 48/211 reads (23%) | catalogued as rs779428016, COSV101258211, COSV67241507; called by muse, mutect2, varscan2
- LRP4 | c.2115C>A p.N705K | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV101066747; called by muse, mutect2
- LYAR | c.393C>G p.D131E | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV100603530, COSV58643830; called by muse, mutect2, varscan2
- MC2R | c.241A>T p.N81Y | Missense Mutation (SNP) | VAF 119/164 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs762270285, COSV100563092; called by muse, mutect2, varscan2
- MRGPRX1 | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs150108666, COSV57107342; called by muse, mutect2, varscan2
- NEDD1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 112/243 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs750626795, COSV99901170; called by muse, mutect2, varscan2
- OR11H4 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs753438056, COSV100197559; called by muse, mutect2, varscan2
- OR13H1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 66/268 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV100088333; called by muse, mutect2, varscan2
- OR1L4 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV99413918; called by muse, mutect2
- PAMR1 | c.1942T>C p.F648L (on ENST00000619888 / NM_001001991.3; = p.F665L on NM_015430.4) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.259); catalogued as COSV99552915; called by muse, mutect2, varscan2
- PARP8 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.968); catalogued as rs1239600215, COSV55863353; called by muse, mutect2, varscan2
- PLCE1 | c.116C>G p.S39* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | catalogued as COSV99596023; called by muse, mutect2, varscan2
- PLEK2 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99371874; called by muse, mutect2, varscan2
- PLPPR4 | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 23/470 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV64565087, COSV64566351; called by muse, mutect2
- PRB3 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 66/489 reads (13%) | catalogued as rs533793961, COSV54389356; called by muse, mutect2, varscan2
- RIMS1 | c.4045G>A p.A1349T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763142023, COSV99328600; called by muse, mutect2, varscan2
- SERPINB10 | c.1194A>T p.*398Yext*19 | Nonstop Mutation (SNP) | VAF 45/281 reads (16%) | catalogued as COSV99449476; called by muse, mutect2, varscan2
- SLC39A12 | c.1095G>C p.E365D | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV66197935; called by muse, mutect2, varscan2
- SORCS3 | c.3161C>A p.T1054N | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100865417; called by muse, mutect2, varscan2
- SSH1 | c.2688G>T p.K896N | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as rs148301801; called by muse, mutect2, varscan2
- SYNE1 | c.6628G>C p.E2210Q (on ENST00000367255 / NM_182961.4; = p.E2217Q on NM_033071.3) | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV54992107; called by muse, mutect2
- SZT2 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs755334344, COSV101285378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TET1 | c.2933C>G p.S978C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV65382446; called by muse, mutect2, varscan2
- TTC1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99180652; called by muse, mutect2
- TTC23 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs749821385, COSV50441441; called by muse, mutect2, varscan2
- ZHX3 | c.2272_2275del p.K758Wfs*9 | Frame Shift Del (DEL) | VAF 18/129 reads (14%) | catalogued as rs1365421969; called by pindel, varscan2
- ZNF407 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs966604763, COSV55262064, COSV99995000; called by muse, mutect2
- ZNF610 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV100016918; called by muse, mutect2, varscan2
- YLPM1 | c.801_802del p.S267Rfs*8 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- ADGRG1 | c.846G>A p.G282= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1303436310, COSV101113481; called by muse, mutect2, varscan2
- ARHGEF11 | c.243C>T p.A81= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs770930971, COSV63815307; called by muse, mutect2, varscan2
- ATP1A2 | c.2025C>T p.L675= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs1185155908, COSV63404684; called by muse, mutect2, varscan2
- CACNA1S | c.1740C>G p.L580= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV100755188; called by muse, mutect2, varscan2
- CHI3L1 | c.618C>T p.Y206= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs372434583; called by muse, mutect2, varscan2
- CTSL | c.318C>T p.F106= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV100446711; called by muse, mutect2, varscan2
- EARS2 | c.1194C>T p.Y398= | Silent (SNP) | VAF 28/223 reads (13%) | catalogued as rs369291371, CM123404; called by muse, mutect2, varscan2
- HYOU1 | c.507C>T p.I169= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs782767234, COSV101345632; called by muse, mutect2
- LPAR5 | c.882G>A p.P294= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs763252050, COSV100321060; called by muse, mutect2, varscan2
- MBD5 | c.1023A>G p.P341= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV101290175; called by muse, mutect2, varscan2
- OR51F2 | c.741C>A p.I247= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV100438093; called by muse, mutect2, varscan2
- RGS7 | c.1323C>T p.S441= | Silent (SNP) | VAF 26/247 reads (11%) | catalogued as rs748233829, COSV100469242, COSV58545346; called by muse, mutect2
- RIMBP2 | c.675C>T p.P225= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV55463629, COSV99899985; called by muse, mutect2, varscan2
- SYNE1 | c.26136C>T p.V8712= (on ENST00000367255 / NM_182961.4; = p.V8664= on NM_033071.3) | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99572250; called by muse, mutect2, varscan2
- ZNF208 | c.1311C>T p.S437= | Silent (SNP) | VAF 16/207 reads (8%) | catalogued as COSV101237142; called by muse, mutect2
- MIR147A | n.9G>T | RNA (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2, varscan2
